Gene-level copy-number profile of tumor specimen C3L-02970-03 from CPTAC case C3L-02970, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.9 years (21,524 days).
Specimen C3L-02970-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 882d746b-f31f-4401-beab-2d4b4b3686e4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02970-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/e576eacd-3908-4663-8a82-3dc38793d022

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 7,152; copy number 2: 45,827; copy number 3: 5,655; copy number 4: 2; copy number 29: 42; copy number 36: 15; copy number 45: 17; copy number 49: 16; copy number 62: 28; copy number 95: 26; copy number 100: 2; copy number 108: 10; copy number 115: 1.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,106,543–25,089,151, 69 genes (broad region; genes not listed).
- chr9:27,198,287–27,944,497, 13 genes (within-gene range 0–2): RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr9:28,148,211–28,149,236, 1 gene (within-gene range 0–2): AL451124.1.
- chr10:79,661,394–79,826,594, 1 gene (within-gene range 0–1): NUTM2B-AS1.
- chr10:79,703,227–79,827,602, 2 genes: NUTM2B, AL135925.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 157 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:52,891,837–57,837,046, 157 genes, copy number 29–115 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,329. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
